Somatic mutation profile of tumor specimen ALCH-AEQA-TTP1-A (aliquot ALCH-AEQA-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEQA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.0 years (27,406 days).
Specimen ALCH-AEQA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 951ccaa9-2199-43ae-b236-c06063d75b36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEQA-NB1-A (Blood Derived Normal), aliquot ALCH-AEQA-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0055957-bc1d-4656-9f83-0cef4e23e7b6

The open-access MAF lists 57 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 10, Intron 4, Nonsense Mutation 3, 3'Flank 1, RNA 1, In Frame Del 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 34/205 reads (17%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 99/622 reads (16%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- SLC12A3 | c.2660G>A p.R887Q (on ENST00000563236 / NM_001126108.2; = p.R896Q on NM_000339.3) | Missense Mutation (SNP) | VAF 104/575 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs369360334, CM033815, COSV52634851; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C2orf16 | c.2474C>A p.T825K | Missense Mutation (SNP) | VAF 48/393 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs746769493; called by muse, mutect2, varscan2
- CTTNBP2NL | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs757311485; called by muse, mutect2, varscan2
- FAT2 | c.9562C>T p.R3188C | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV55826239; called by muse, mutect2, varscan2
- GPLD1 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs777612304; called by muse, mutect2, varscan2
- IGFN1 | c.2515C>T p.R839W (on ENST00000295591 / NM_001367841.1; = p.R3296W on NM_001164586.2) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs532291490; called by muse, mutect2, varscan2
- LLGL1 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV57501225; called by muse, mutect2
- MYO3B | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753788691, COSV58695762; called by muse, mutect2
- NUP107 | c.2146C>G p.P716A | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57494157; called by muse, mutect2
- PDZRN4 | c.1283C>A p.T428N (on ENST00000402685 / NM_001164595.2; = p.T170N on NM_013377.4) | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV100114529, COSV54211551; called by muse, varscan2
- PNPLA3 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1317667080; called by muse, mutect2, varscan2
- POLE | c.5215A>G p.I1739V | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.026); catalogued as rs1064794641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRT | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.909); catalogued as rs879079672; called by muse, mutect2
- RPL5 | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 52/666 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100240269; called by muse, mutect2
- SLCO1B3 | c.460T>C p.S154P | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV99682138; called by muse, mutect2, varscan2
- SLIT1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1179390198; called by muse, mutect2, varscan2
- SPOUT1 | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV56917333; called by muse, mutect2, varscan2
- SPPL2B | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs974637777; called by muse, mutect2, varscan2
- ZNF334 | c.527T>A p.L176* | Nonsense Mutation (SNP) | VAF 65/382 reads (17%) | catalogued as COSV100749149; called by muse, mutect2, varscan2
- ANAPC1 | c.4478A>C p.K1493T | Missense Mutation (SNP) | VAF 41/318 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGFL8 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR1 | c.804G>T p.W268C | Missense Mutation (SNP) | VAF 70/389 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- GRIN2B | c.3140A>G p.D1047G | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HOXA1 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 56/388 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- IGLV11-55 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 42/187 reads (22%) | called by muse, mutect2, varscan2
- MAS1L | c.874T>G p.F292V | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- NLRP7 | c.2348A>C p.Y783S (on ENST00000340844 / NM_206828.3; = p.Y755S on NM_139176.3) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OPRL1 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.087); called by muse, mutect2
- OVCH1 | c.304G>C p.V102L | Missense Mutation (SNP) | VAF 59/586 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- POT1 | c.128A>C p.Y43S | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PTCHD4 | c.774G>C p.L258F | Missense Mutation (SNP) | VAF 20/426 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2
- ROCK2 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 51/319 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SVIL | c.2434A>C p.T812P (on ENST00000355867 / NM_021738.3; = p.T386P on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/512 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TMIGD1 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 97/531 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TTPA | c.627G>T p.M209I | Missense Mutation (SNP) | VAF 94/582 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBA1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XKR5 | c.1192T>A p.S398T | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- C1orf94 | c.1080C>T p.S360= (on ENST00000488417 / NM_001134734.2; = p.S170= on NM_032884.5) | Silent (SNP) | VAF 32/367 reads (9%) | called by muse, mutect2
- C7orf31 | c.840G>A p.S280= | Silent (SNP) | VAF 30/390 reads (8%) | catalogued as rs778627102; called by muse, mutect2
- DEAF1 | c.696G>A p.E232= | Silent (SNP) | VAF 60/352 reads (17%) | catalogued as rs761590763, COSV100102424; called by muse, mutect2, varscan2
- FREM1 | c.6285C>T p.S2095= | Silent (SNP) | VAF 52/301 reads (17%) | called by muse, mutect2, varscan2
- KCNU1 | c.2364G>A p.A788= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as rs753941106, COSV67755817; called by muse, mutect2, varscan2
- NME9 | c.222C>T p.L74= (on ENST00000333911 / NM_001349024.2; = p.L52= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/320 reads (15%) | catalogued as COSV100444609; called by muse, mutect2, varscan2
- OPRL1 | c.81C>A p.P27= | Silent (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- SLC22A18 | c.312G>A p.L104= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100388662; called by muse, mutect2, varscan2
- SSUH2 | c.66G>A p.T22= | Silent (SNP) | VAF 45/274 reads (16%) | catalogued as rs749480428; called by muse, mutect2, varscan2
- ZNF613 | c.408G>C p.L136= (on ENST00000293471 / NM_001031721.4; = p.L100= on NM_024840.4) | Silent (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- AC109361.1 | n.3142G>A | RNA (SNP) | VAF 52/255 reads (20%) | catalogued as rs1487690033; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501958 del AA | 5'Flank (DEL) | VAF 24/186 reads (13%) | catalogued as rs771833705; called by mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs73150876; called by muse, mutect2, varscan2
- FGF3 | c.-22G>A | 5'UTR (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
- LYRM4 | c.207+29781T>G | Intron (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- SIGMAR1 | c.152-30C>G | Intron (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210164106 C>T | 3'Flank (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- UTS2B | c.334+1762C>G | Intron (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
